Somatic mutation profile of tumor specimen TCGA-DD-A1EA-01A (aliquot TCGA-DD-A1EA-01A-11D-A12Z-10) from TCGA case TCGA-DD-A1EA, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 68.2 years (24,925 days).
Specimen TCGA-DD-A1EA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e444f68-aa6e-46e5-aa9b-66dcb94c8bce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A1EA-10A (Blood Derived Normal), aliquot TCGA-DD-A1EA-10A-01D-A12Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c24cbe0b-57f2-48c7-80fb-1dc1a11edc8e

The open-access MAF lists 89 somatic variants for this specimen: 75 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 13, Nonsense Mutation 4, Frame Shift Ins 2, In Frame Del 1, Frame Shift Del 1, Splice Site 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.92_106del p.L31_I35del | In Frame Del (DEL) | VAF 42/157 reads (27%) | hotspot (GDC flag); called by mutect2, varscan2
- AKAP11 | c.4238C>A p.S1413* | Nonsense Mutation (SNP) | VAF 16/51 reads (31%) | catalogued as COSV50292866; called by muse, mutect2, varscan2
- AMY2A | c.266G>C p.G89A | Missense Mutation (SNP) | VAF 322/884 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70214287, COSV70214761; called by muse, mutect2, varscan2
- AQR | c.1705C>A p.P569T | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV50029838; called by muse, mutect2, varscan2
- ARMC10 | c.899A>G p.Q300R | Missense Mutation (SNP) | VAF 138/506 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.022); catalogued as rs1168473664, COSV58521309; called by muse, mutect2, varscan2
- ATCAY | c.832C>T p.R278W | Missense Mutation (SNP) | VAF 57/124 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376658701; called by muse, mutect2, varscan2
- ATP1A1 | c.1214A>C p.N405T | Missense Mutation (SNP) | VAF 60/175 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.248); catalogued as COSV55189759; called by muse, mutect2, varscan2
- ATP2B2 | c.542G>T p.G181V | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59490006; called by muse, mutect2, varscan2
- ATP5MC3 | c.74T>A p.I25N | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV52976099; called by muse, mutect2, varscan2
- CACNA1B | c.1887G>T p.Q629H | Missense Mutation (SNP) | VAF 98/267 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53115013; called by muse, mutect2, varscan2
- CCDC146 | c.1726A>G p.N576D | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV53544266; called by muse, mutect2, varscan2
- CES4A | c.1074G>T p.L358F | Missense Mutation (SNP) | VAF 73/201 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV58651727; called by muse, mutect2, varscan2
- CHRM3 | c.619T>A p.W207R | Missense Mutation (SNP) | VAF 321/523 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55081060; called by muse, mutect2, varscan2
- CLSTN1 | c.1802C>A p.A601D (on ENST00000377298 / NM_001009566.3; = p.A591D on NM_014944.4) | Missense Mutation (SNP) | VAF 86/198 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV63646730; called by muse, mutect2, varscan2
- CNKSR2 | c.988G>A p.V330I | Missense Mutation (SNP) | VAF 149/162 reads (92%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs759498814, COSV54249894; ClinVar: benign; called by muse, mutect2, varscan2
- CNOT11 | c.1414A>T p.I472L | Missense Mutation (SNP) | VAF 70/175 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.957); catalogued as COSV56819045; called by muse, mutect2, varscan2
- COL15A1 | c.649-1G>A p.X217_splice | Splice Site (SNP) | VAF 23/57 reads (40%) | catalogued as rs1354262734, COSV66641499; called by muse, mutect2, varscan2
- CPA6 | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 56/146 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.539); catalogued as COSV52721363; called by muse, mutect2, varscan2
- CREBBP | c.6428A>G p.N2143S | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV52114804; called by muse, mutect2, varscan2
- DAAM1 | c.2369T>A p.V790E | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100658441, COSV62834277; called by muse, mutect2, varscan2
- DDX59 | c.751T>A p.S251T | Missense Mutation (SNP) | VAF 92/396 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV58750523; called by muse, mutect2, varscan2
- DHRS4 | c.644T>G p.I215S | Missense Mutation (SNP) | VAF 240/1121 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57479940; called by muse, mutect2, varscan2
- DIP2C | c.3313G>T p.V1105F | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.47); PolyPhen benign (0.088); catalogued as COSV55146988; called by muse, mutect2, varscan2
- DKK2 | c.581G>A p.C194Y | Missense Mutation (SNP) | VAF 74/169 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53394445, COSV53404835; called by muse, mutect2, varscan2
- DPF3 | c.710C>T p.S237F | Missense Mutation (SNP) | VAF 153/408 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as rs1261327739, COSV63498885; called by muse, mutect2, varscan2
- DYRK3 | c.403G>T p.A135S | Missense Mutation (SNP) | VAF 162/263 reads (62%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV65605442; called by muse, mutect2, varscan2
- EIF4A2 | c.641C>T p.S214F | Missense Mutation (SNP) | VAF 144/375 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV56215619, COSV56217352; called by muse, mutect2, varscan2
- ESPNL | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.081); catalogued as rs1272598722, COSV54540222; called by muse, mutect2
- FEM1C | c.796T>G p.L266V | Missense Mutation (SNP) | VAF 60/209 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.139); catalogued as COSV57230819; called by muse, mutect2, varscan2
- FLT4 | c.2885C>A p.A962D | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.027); catalogued as COSV56099143; called by muse, mutect2
- FNDC7 | c.1246G>A p.D416N | Missense Mutation (SNP) | VAF 83/182 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54751000; called by muse, mutect2, varscan2
- FOXG1 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57395336; called by muse, mutect2, varscan2
- FUZ | c.362T>C p.V121A | Missense Mutation (SNP) | VAF 64/181 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as COSV58240856; called by muse, mutect2, varscan2
- GGA2 | c.1214C>T p.P405L | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV59167461; called by muse, mutect2, varscan2
- GPRIN3 | c.716C>T p.T239I | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV60884163, COSV60884267; called by muse, mutect2, varscan2
- GYPE | c.68C>A p.T23N | Missense Mutation (SNP) | VAF 186/1024 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.632); catalogued as COSV62261493; called by muse, varscan2
- H6PD | c.501G>A p.W167* | Nonsense Mutation (SNP) | VAF 18/36 reads (50%) | catalogued as COSV66230299; called by muse, mutect2, varscan2
- HERC2 | c.7644C>G p.S2548R | Missense Mutation (SNP) | VAF 130/343 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as COSV55308827; called by muse, mutect2, varscan2
- ICAM5 | c.1750T>C p.W584R | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.641); catalogued as COSV55746194; called by muse, mutect2, varscan2
- IFNA8 | c.389T>C p.I130T | Missense Mutation (SNP) | VAF 100/234 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs28383787, COSV66504297; called by muse, mutect2, varscan2
- IL12RB2 | c.2486T>C p.L829P | Missense Mutation (SNP) | VAF 119/308 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV52020519; called by muse, mutect2, varscan2
- IL21R | c.1114G>T p.G372C | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61968589; called by muse, mutect2, varscan2
- IRS4 | c.2989C>T p.L997F | Missense Mutation (SNP) | VAF 97/105 reads (92%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs189095515, COSV64532744; called by muse, mutect2, varscan2
- KCNB2 | c.745C>G p.L249V | Missense Mutation (SNP) | VAF 103/272 reads (38%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.888); catalogued as COSV73049014; called by muse, mutect2, varscan2
- LRP12 | c.683A>G p.K228R | Missense Mutation (SNP) | VAF 97/209 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1321018638, COSV52625862; called by muse, mutect2, varscan2
- MAST2 | c.1426A>G p.M476V | Missense Mutation (SNP) | VAF 133/305 reads (44%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.027); catalogued as rs375425588; called by muse, mutect2, varscan2
- MED13 | c.1531A>G p.I511V | Missense Mutation (SNP) | VAF 142/503 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0.074); catalogued as COSV67262072; called by muse, mutect2, varscan2
- MED13L | c.3349G>A p.D1117N | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as COSV56116142; called by muse, mutect2, varscan2
- MEIS1 | c.365C>A p.A122D | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.652); catalogued as COSV55483705; called by muse, mutect2, varscan2
- MRPL49 | c.4G>C p.A2P | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53694673; called by muse, mutect2, varscan2
- MRPS22 | c.43A>T p.R15W | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.325); catalogued as COSV60349127; called by muse, mutect2, varscan2
- MYNN | c.1718A>G p.H573R | Missense Mutation (SNP) | VAF 83/267 reads (31%) | SIFT tolerated, low confidence (0.31); PolyPhen possibly damaging (0.84); catalogued as COSV62990961; called by muse, mutect2, varscan2
- NPY2R | c.487C>G p.R163G | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.091); catalogued as COSV61527268, COSV61528909; called by muse, mutect2, varscan2
- OGDHL | c.2158G>T p.A720S | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.043); catalogued as COSV65101069; called by muse, mutect2, varscan2
- PAM | c.124T>A p.C42S | Missense Mutation (SNP) | VAF 63/221 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57209685; called by muse, mutect2, varscan2
- PBRM1 | c.1414C>T p.R472* | Nonsense Mutation (SNP) | VAF 54/92 reads (59%) | catalogued as COSV56262370; called by muse, mutect2, varscan2
- PEAK1 | c.3850G>T p.E1284* | Nonsense Mutation (SNP) | VAF 78/215 reads (36%) | catalogued as COSV56931299; called by muse, mutect2, varscan2
- PHF10 | c.1342A>G p.M448V | Missense Mutation (SNP) | VAF 48/145 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV59321115; called by muse, mutect2, varscan2
- PIK3C2G | c.1928A>T p.E643V (on ENST00000676171; = p.E602V on NM_004570.5) | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.84); catalogued as COSV56797843; called by muse, varscan2
- PTPN3 | c.482A>G p.Y161C | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1275704877, COSV52702214; called by muse, mutect2, varscan2
- RFXAP | c.616A>G p.I206V | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.085); catalogued as COSV55225440; called by muse, mutect2, varscan2
- SIPA1L1 | c.4316G>A p.S1439N | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.883); catalogued as COSV62168654; called by muse, mutect2, varscan2
- SYNGR1 | c.561C>A p.D187E | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.292); catalogued as COSV59559422; called by muse, mutect2, varscan2
- TAF7L | c.128A>T p.Y43F | Missense Mutation (SNP) | VAF 194/212 reads (92%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV63299339; called by muse, mutect2, varscan2
- TCEA1 | c.195G>T p.L65F | Missense Mutation (SNP) | VAF 128/353 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV67172083; called by muse, mutect2, varscan2
- TRIM46 | c.1285G>T p.V429L | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.096); catalogued as COSV58111530; called by muse, mutect2, varscan2
- TYMS | c.804G>A p.Q268= | Splice Region (SNP) | VAF 54/137 reads (39%) | catalogued as rs766563822, COSV51890611; called by muse, mutect2, varscan2
- USP49 | c.1033A>C p.I345L | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as COSV51894930; called by muse, mutect2, varscan2
- VPS13A | c.1115del p.K372Sfs*2 | Frame Shift Del (DEL) | VAF 8/66 reads (12%) | catalogued as rs770350986; called by mutect2, varscan2
- VPS4B | c.597A>G p.I199M | Missense Mutation (SNP) | VAF 79/190 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV53068516; called by muse, mutect2, varscan2
- ZFYVE26 | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs267604034, COSV61324835; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZSCAN1 | c.1156G>A p.G386R | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs750088775, COSV56601973; called by muse, mutect2, varscan2
- APOB | c.2628dup p.P877Tfs*20 | Frame Shift Ins (INS) | VAF 45/112 reads (40%) | called by mutect2, varscan2
- PEG10 | c.832C>T p.R278C (on ENST00000482108 / NM_001040152.2; = p.R312C on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- RPS6KL1 | c.1213dup p.E405Gfs*62 | Frame Shift Ins (INS) | VAF 30/70 reads (43%) | called by mutect2, varscan2
- ANKRD11 | c.3180A>G p.K1060= | Silent (SNP) | VAF 110/266 reads (41%) | catalogued as COSV56355463; called by muse, mutect2, varscan2
- ATP13A3 | c.3615C>T p.A1205= (on ENST00000645319 / NM_001367549.1; = p.A1175= on NM_024524.3) | Silent (SNP) | VAF 72/183 reads (39%) | catalogued as rs1477686201, COSV55461787; called by muse, mutect2, varscan2
- CAB39 | c.30A>G p.K10= | Silent (SNP) | VAF 98/238 reads (41%) | catalogued as COSV51474469; called by muse, mutect2, varscan2
- DAZL | c.246T>C p.Y82= | Silent (SNP) | VAF 63/182 reads (35%) | catalogued as COSV51711918; called by muse, mutect2, varscan2
- DGAT2 | c.726T>G p.A242= | Silent (SNP) | VAF 32/88 reads (36%) | catalogued as COSV57175277, COSV57175358; called by muse, varscan2
- IMPA1 | c.258A>G p.T86= | Silent (SNP) | VAF 60/156 reads (38%) | catalogued as rs374631061; called by muse, mutect2, varscan2
- KCNJ11 | c.354G>A p.S118= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as rs140636367; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- KCNT2 | c.1623A>G p.R541= | Silent (SNP) | VAF 40/189 reads (21%) | catalogued as COSV54065220; called by muse, mutect2, varscan2
- MTREX | c.528A>G p.A176= | Silent (SNP) | VAF 100/183 reads (55%) | catalogued as rs1024992549, COSV57924098; called by muse, mutect2, varscan2
- PLCB4 | c.312A>C p.T104= | Silent (SNP) | VAF 36/114 reads (32%) | catalogued as COSV53793900; called by muse, mutect2, varscan2
- SLITRK1 | c.1377C>T p.I459= | Silent (SNP) | VAF 45/140 reads (32%) | catalogued as COSV65674405; called by muse, mutect2, varscan2
- SSC4D | c.231C>A p.G77= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV51881370; called by muse, mutect2, varscan2
- TBCK | c.2073A>G p.E691= (on ENST00000273980 / NM_001163436.4; = p.E628= on NM_033115.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 89/235 reads (38%) | catalogued as COSV56752157; called by muse, mutect2, varscan2
- RPL26P30 | n.647G>T | RNA (SNP) | VAF 24/61 reads (39%) | called by muse, mutect2, varscan2
